Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A6B0, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A6B0-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:
Med. Rec. #:

DOB: (Age:)
Gender: M
Ref. Physician:
Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Diagnosed to have a very large bladder tumor. Right side of bladder wall hydroureteronephrosis, right bladder cancer.

Specimens Submitted:

- 1: SP: Ureter, left distal, excision (fs)
- 2: SP: Ureter, right distal, excision (fs)
- 3: SP: Urethra margin, distal, excision (fs)
- 4: SP: Bladder, prostate, seminal vesicles, radical cystoprostatectomy
- 5: SP: Lymph nodes, left pelvic, excision
- 6: SP: Lymph nodes, right pelvic, excision

DIAGNOSIS:

1. Ureter, left distal, excision (fs) :
- Benign ureter wall tissue.

2. Ureter, right distal, excision (fs) :
- Benign ureter wall tissue

3. Urethra, distal margin, excision (fs) :
- Benign ureter wall tissue

4. SP: Bladder, prostate, seminal vesicles, radical cystoprostatectomy
a.

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary

A significant part of non-invasive component consists of low grade papillary carcinoma

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Deep half of muscularis propria

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

IOD-0-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder, lateral wall
C67.2
JW 6/18/13

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Vascular Invasion:

Not identified
supported by immunostains for CD31 and D2-40

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Prior biopsy site changes.

Prostate:

Other prostatic adenocarcinoma.

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT2b (Invades deep half of muscularis propria)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

Tumor Location:

Involves Right posterior

Involves Right anterior

Two incidental microscopic foci of adenocarcinoma identified in right anterior apex and right posterior mid measuring 0.5 cm and 0.7 cm respectively.

Vascular Invasion:

Not Identified

Perineural Invasion:

Not identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Not Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Non-Neoplastic Prostate:
Exhibits nodular hyperplasia

Staging (AJCC 1997):
pT2a (confined to the prostate & capsule, involving one lobe)

5. SP: Lymph nodes, left pelvic, excision :

Lymph Nodes:
Not involved
Number of nodes examined:4
The immunostain for AE1/AE3 supports the diagnosis

6. SP: Lymph nodes, right pelvic, excision :

Lymph Nodes:
Not involved
Number of nodes examined:12
Fragment of benign vas deferens

Note. Selected slides of the case were reviewed with Dr. who agreed with the interpretation.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	D2-40	
	CD31	
	NEG CONT	
	IMM RECUT	
	AE1:AE3	
	NEG CONT	
	IMM RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Left distal ureter, freeze end opposite clip" and consists of a portion of ureter measuring 1.2 cm in length and 0.3 cm in diameter. The opposite area to the clip is representatively submitted for frozen section. The remaining tissue is trisected and entirely submitted.

Summary of sections:
FSC -- frozen section control
C-E-clipped end
RT-remaining tissue

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

2). The specimen is received fresh for frozen section consultation, labeled "Right distal ureter, freeze end opposite clip" and consists of a portion of ureter measuring 1.3 cm in length and 0.5 cm in diameter. The area opposite to the clip is representatively submitted for frozen section. The remaining tissue is trisected and entirely submitted.

Summary of sections:

FSC -- frozen section control

C-E-clipped end

RT- remaining

3). The specimen is received fresh for frozen section consultation, labeled "Distal urethra margin" and consists of a single pink-tan soft tissue measuring 0.3 x 0.6 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

4). The specimen is received fresh, labeled "Bladder, prostate and seminal vesicles". It consists of a radical cystoprostatectomy specimen measuring 18.5 cm from superior to inferior, 12.1 cm laterally and 3.9 cm from anterior to posterior. The bladder measures 8.5 x 8.0 x 3.5 cm, the prostate measures 4.0 x 4.5 x 3.2 cm, the right seminal vesicle measures 3.0 x 1.2 x 1.2 cm, the right vas deferens measures 6.5 x 0.5 x 0.7 cm, the left seminal vesicle measures 3.3 x 1.5 x 1.2 cm and the left vas deferens measures 6.8 x 0.5 x 0.5 cm. The anterior and posterior aspect of the bladder is inked black. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a fungating friable red-brown tumor measuring 6.5 x 6.0 x 3.8 cm which is situated within the right lateral and posterior bladder wall. The lesion measures 1.7 cm from the left orifice and grossly surrounds the right orifice. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal the tumor that grossly extends into but not through the muscularis propria. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is hemorrhagic and focally ulcerated. Discrete perivesical lymph nodes are grossly not identified. The right prostate is inked green and the left prostate is inked blue. The prostate is serially sectioned to reveal tan-yellow whorled cut surface and no discrete masses or lesions. Representative sections are submitted including three sections from each prostatic quadrant and transition zone. The specimen is photographed. TPS is submitted.

Summary of sections:

UM -- urethral margin

RUM-- right ureter margin.

LUM -- left ureter margin.

L-- lesion.

RUO -- right ureter orifice.

LUO-- left ureter orifice.

LP -- left posterior wall.

LA -- left anterior wall.

RP -- right posterior wall.

RA-- right anterior wall.

TRI -- trigone.

DOM-- dome.

F -- perivesical fat.

RSV -- right seminal vesicle

LSV -- left seminal vesicle

RAP -- right apex prostate

LA P-- left apex prostate

RAM -- right anterior mid prostate

RPM -- right posterior mid prostate

LAM -- left anterior mid prostate

LPM -- left posterior mid prostate

RAB -- right anterior base prostate

RPB -- right posterior base prostate

LAB -- left anterior base prostate

LPB -- left posterior base prostate

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

5). The specimen is received fresh, labeled "left pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.7 to 1.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes (single lymph node bisected and submitted in two cassettes)

6). The specimen is received fresh, labeled "Right pelvic lymph nodes" and consists of seven pink tan lymph nodes, ranging in size from 0.5 to 2.9 cm in greatest dimension. Separately received in the container, is a smooth pink-tan tubular segment of tissue measuring 3.5 cm in length and 0.2 cm in diameter. On sectioning, a possible pinpoint lumen and no additional discrete abnormalities are grossly noted. All the lymph nodes and representative sections of the tubular segment of tissue are submitted.

Summary of sections:

E - ends of tubular segment

C - center of tubular segment

SLN - trisected node

BLN - bisected node

LN-lymph nodes submitted whole

Summary of Sections:

Part 1: SP: Ureter, left distal, excision (fs)

Block	Sect. Site	PCs
1	C-E	1
1	FSC	1
1	RT	1

Part 2: SP: Ureter, right distal, excision (fs)

Block	Sect. Site	PCs
1	C-E	1
1	FSC	1
1	RT	1

Part 3: SP: Urethra margin, distal, excision (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 4: SP: Bladder, prostate, seminal vesicles, radical cystoprostatectomy

Block	Sect. Site	PCs
1	dom	1
1	f	1
6	l	6
1	la	1
1	lab	1
1	lam	1
1	lap	1
1	lp	1
1	lpb	1
1	lpm	1
1	lsv	1
1	lum	1
1	luo	1
1	ra	1
1	rab	1

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1	ram	1
1	rap	1
1	rp	1
1	rpb	1
1	rpm	1
1	rsv	1
1	rum	1
1	ruo	1
1	tri	1
1	um	1

Part 5: SP: Lymph nodes, left pelvic, excision

Block	Sect. Site	PCs
2	bln	2
2	ln	2

Part 6: SP: Lymph nodes, right pelvic, excision

Block	Sect. Site	PCs
2	bln	2
1	c	1
1	e	1
2	ln	2
1	sln	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN URETER.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN URETER.
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME

Area	W 5/5/13	Yes	No
agnotis Discrepancy			✓
mary Tumor Site Discrepancy			✓
PAA Discrepancy			✓
for Malignancy History			✓
al Synchronous Primary Tumor	prostate	✓	

Source: NCI Genomic Data Commons file 8b446eb8-3673-4ce7-a800-3aac8f0f8c3e (TCGA-DK-A6B0.39DA362A-CFF2-4A9B-AAC9-963AA207AB37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).